Surgical pathology report (de-identified scan), TCGA case TCGA-GF-A2C7, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site ABS - IUPUI, specimen TCGA-GF-A2C7-01A (Primary Tumor).

[page 1 of 6]
Final Pathologic Diagnosis:

- A. Skin, upper back, punch biopsy:
Combined nevus (intradermal nevus and blue nevus)
- B. Skin and subcutaneous soft tissue, scalp, vertex, excision:
Nodular ulcerative basal cell carcinoma
Margins are negative for malignancy, however the tumor is less than 1 mm from the right inferior margin.
- C. Lymph node, left posterior triangle, excision:
2 lymph nodes negative for malignancy (0/2)
- D. Lymph node, sentinel, excision:
Benign fibroadipose tissue
No lymph node present
- E. Skin and subcutaneous soft tissue, scalp, wide excision:
Malignant melanoma, see below

ICD-0-3

Melanoma, NOS 8720/3

Site: Skin, scalp C44.4

hw
6/1/11

Procedure	Wide excision
Site	Scalp
Laterality	Posterior
Type	Nodular
Thickness	7 mm
Level	Clark's level IV
Ulceration	Present
Mitosis/mm2	2/mm2
Microsatellitosis	Not identified
Lymphovascular invasion	Not identified
Regression	Not identified
Perineural invasion	Not identified
Tumor infiltrating lymphocytes	Sparse
Satellite nodule (gross finding)	Not identified
Margin status	Margins free
Excisions, margin free, distance from margin (deep margin)	7 mm from closest margin
Sentinel node, number of lymph nodes	none
Non-sentinel lymph nodes	2 (see part C)
Number of positive lymph nodes	0
Extracapsular spread	n/a
Size of largest metastatic focus	n/a
Location of tumor (subcapsular sinus, parenchyma)	n/a

pT4b, N0, MX

[page 2 of 6]
The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

The specimens are received in five containers labeled with the patient name.

Part A is received in formalin labeled "upper back biopsy" and consists of a punch biopsy that is 4 mm. The specimen is inked, bisected and submitted in cassette A.

B is received in formalin labeled "vortex scalp, short suture is left margin, long suture is superior margin" and consists of a ovoid skin excision 2.7 x 2.1 cm excised to a depth of 0.7 cm. There are two sutures present, the short suture designated left and the long suture superior. The long suture will now be designated 12 o'clock and the short suture 9 o'clock. The specimen is inked as follows: 9 to 12 to 3 black, 3 to 6 to 9 blue. The 9 o'clock edge is submitted in cassette B1, the 3 o'clock edge in cassette B2, the remaining specimen is submitted sequentially from 9 to 3 o'clock in cassettes B3 through B7.

Part C is labeled "left posterior triangle node" and consists of a single pink-tan possible lymph node 1.8 x 1.2 x 0.7 cm. The specimen is sectioned and entirely submitted in cassette C1 and C2.

D is labeled "possible sentinel node left posterior ear" and consists of a yellow-tan possible lymph node 1.5 x 1.1 x 1 cm. The specimen is sectioned and entirely submitted in cassette D1 through D3. Four unstained slides requested on cassettes D1 and D2.

Part E is received fresh for Tissue Procurement subsequently placed in formalin labeled "scalp melanoma, short suture superior, long suture left lateral" and consists of a roughly ovoid skin excision 7 x 6.2 cm excised to the depth of 1.1 cm. There are two sutures present, the short designated superior and the long left lateral. The short suture will now be designated 12 o'clock and the long suture 9 o'clock. The surface of the skin is remarkable for a pink-tan to gray-tan exophytic lesion 2.5 x 1.7 x 0.8 cm. The remaining skin is remarkable for blue surgical dye. The specimen is inked as follows: 9 to 12 to 3 black, 3 to 6 to 9 blue. The specimen is sectioned and entirely submitted as follows:

- E1 9 o'clock edge;
- E2,3 full-thickness cross-sections;
- E4,5 one contiguous cross-section bisected;
- E6,7 one contiguous cross-section bisected;
- E8,9 one contiguous cross-section bisected;
- E10,11 one contiguous cross-section bisected;
- E12,13 one contiguous cross-section bisected;

[page 3 of 6]
E14-16 one contiguous cross-section trisected;
E17-19 one contiguous cross-section trisected;
E20-22 one contiguous cross-section trisected;
E23,24 one contiguous cross-section bisected;
E25,26 one contiguous cross-section bisected;
E27,28 one contiguous cross-section bisected;
E29,30 one contiguous cross-section bisected;
E31,32 one contiguous cross-section bisected;
E33,34 one contiguous cross-section bisected;
E35,36 3 o'clock edge bisected.

END OF REPORT

[page 4 of 6]
Final Pathologic Diagnosis:

- A. Skin, upper back, punch biopsy:
Combined nevus (intradermal nevus and blue nevus)
- B. Skin and subcutaneous soft tissue, scalp, vertex, excision:
Nodular ulcerative basal cell carcinoma
Margins are negative for malignancy, however the tumor is less than 1 mm from the right inferior margin.
- C. Lymph node, left posterior triangle, excision:
2 lymph nodes negative for malignancy (0/2)
- D. Lymph node, sentinel, excision:
Benign fibroadipose tissue
No lymph node present
- E. Skin and subcutaneous soft tissue, scalp, wide excision:
Malignant melanoma, see below

Procedure	Wide excision
Site	Scalp
Laterality	Posterior
Type	Nodular
Thickness	7 mm
Level	Clark' s level IV
Ulceration	Present
Mitosis/mm2	2/mm2
Microsatellitosis	Not identified
Lymphovascular invasion	Not identified
Regression	Not identified
Perineural invasion	Not identified
Tumor infiltrating lymphocytes	Sparse
Satellite nodule (gross finding)	Not identified
Margin status	Margins free
Excisions, margin free, distance from margin (deep margin)	7 mm from closest margin
Sentinel node, number of lymph nodes	none
Non-sentinel lymph nodes	2 (see part C)
Number of positive lymph nodes	0
Extracapsular spread	n/a
Size of largest metastatic focus	n/a
Location of tumor (subcapsular sinus, parenchyma)	n/a

pT4b, N0, MX

[page 5 of 6]
The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

The specimens are received in five containers labeled with the patient name.

Part A is received in formalin labeled "upper back biopsy" and consists of a punch biopsy that is 4 mm. The specimen is inked, bisected and submitted in cassette A.

B is received in formalin labeled "vortex scalp, short suture is left margin, long suture is superior margin" and consists of a ovoid skin excision 2.7 x 2.1 cm excised to a depth of 0.7 cm. There are two sutures present, the short suture designated left and the long suture superior. The long suture will now be designated 12 o'clock and the short suture 9 o'clock. The specimen is inked as follows: 9 to 12 to 3 black, 3 to 6 to 9 blue. The 9 o'clock edge is submitted in cassette B1, the 3 o'clock edge in cassette B2, the remaining specimen is submitted sequentially from 9 to 3 o'clock in cassettes B3 through B7.

Part C is labeled "left posterior triangle node" and consists of a single pink-tan possible lymph node 1.8 x 1.2 x 0.7 cm. The specimen is sectioned and entirely submitted in cassette C1 and C2.

D is labeled "possible sentinel node left posterior ear" and consists of a yellow-tan possible lymph node 1.5 x 1.1 x 1 cm. The specimen is sectioned and entirely submitted in cassette D1 through D3. Four unstained slides requested on cassettes D1 and D2.

Part E is received fresh for Tissue Procurement subsequently placed in formalin labeled "scalp melanoma, short suture superior, long suture left lateral" and consists of a roughly ovoid skin excision 7 x 6.2 cm excised to the depth of 1.1 cm. There are two sutures present, the short designated superior and the long left lateral. The short suture will now be designated 12 o'clock and the long suture 9 o'clock. The surface of the skin is remarkable for a pink-tan to gray-tan exophytic lesion 2.5 x 1.7 x 0.8 cm. The remaining skin is remarkable for blue surgical dye. The specimen is inked as follows: 9 to 12 to 3 black, 3 to 6 to 9 blue. The specimen is sectioned and entirely submitted as follows:

- E1 9 o'clock edge;
- E2,3 full-thickness cross-sections;
- E4,5 one contiguous cross-section bisected;
- E6,7 one contiguous cross-section bisected;
- E8,9 one contiguous cross-section bisected;
- E10,11 one contiguous cross-section bisected;
- E12,13 one contiguous cross-section bisected;

[page 6 of 6]
E14-16 one contiguous cross-section trisected;
E17-19 one contiguous cross-section trisected;
E20-22 one contiguous cross-section trisected;
E23,24 one contiguous cross-section bisected;
E25,26 one contiguous cross-section bisected;
E27,28 one contiguous cross-section bisected;
E29,30 one contiguous cross-section bisected;
E31,32 one contiguous cross-section bisected;
E33,34 one contiguous cross-section bisected;
E35,36 3 o'clock edge bisected.

Taken:'

END OF REPORT

Source: NCI Genomic Data Commons file 6edb169e-cd4c-449e-a505-262a18d1a314 (TCGA-GF-A2C7.C878CC4A-C645-419F-A8A5-4E80066AAFFE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).